Gene-level copy-number profile of tumor specimen TCGA-HC-7740-01B from TCGA case TCGA-HC-7740, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.9 years (21,883 days).
Specimen TCGA-HC-7740-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.ead38efb-2670-4586-84b8-db0a488b52ed.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-7740-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate.
https://portal.gdc.cancer.gov/files/0d2b6edb-6f7d-4468-adff-6fdfe7c90c6f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 2,436; copy number 2: 57,068; copy number 3: 728; copy number 4: 6; copy number 5: 3; copy number 7: 1; copy number 9: 3; copy number 10: 1; copy number 12: 16; copy number 21: 1; copy number 24: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-7740-01A-11D-2112-01): tumor purity 0.22, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–189,972, 3 genes (within-gene range 0–2): AC113430.1, PLEKHG4B, Y_RNA.
- chr10:78,352,597–78,367,623, 2 genes (within-gene range 0–26): AC010163.2, SNORA71.
- chr13:48,340,797–48,341,330, 1 gene: AL392048.1.
- chr13:91,272,081–91,272,577, 1 gene: PPIAP23.
- chr14:96,931,367–97,007,624, 3 genes (within-gene range 0–2): LINC00618, AL049833.3, AL049833.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 26 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:154,754,756–154,781,873, 1 gene, copy number 7 (within-gene range 2–7): AC009567.1.
- chr6:5,997,999–6,007,605, 1 gene, copy number 10: NRN1.
- chr9:94,809,962–94,824,773, 2 genes, copy number 5: MIR2278, AL807757.1.
- chr10:4,201,141–4,243,912, 1 gene, copy number 5 (within-gene range 2–5): LINC00702.
- chr12:48,667,457–48,667,593, 1 gene, copy number 24: SNORA2B.
- chr12:123,633,739–123,662,604, 3 genes, copy number 9 (within-gene range 2–9): GTF2H3, AC117503.3, AC117503.2.
- chr13:48,316,863–48,328,564, 2 genes, copy number 12: PPP1R26P1, PCNPP5.
- chr15:25,054,210–25,081,378, 14 genes, copy number 12: SNORD116-2, SNORD116-3, SNORD116-4, SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15.
- chr22:25,349,543–25,350,322, 1 gene, copy number 21: AL022324.2.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
